Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-7063, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-7063-01A (Primary Tumor).

[page 1 of 4]
Patient Name	MRN	Visit Number

Event Date and Time	Procedure Ordered	Status	Ordered By	Specimen #
	Surgical Pathology Report	complete		
Collection Date				
Accession Date				
Result Date				
Copath#				

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Oral-Cavity: medial margin palate
2. Oral-Cavity: right partial maxillectomy
3. Oral Cavity: Right partial glossectomy- stitch anterior margin
4. Oral Cavity: Deep margin tongue

DIAGNOSIS

1. Medial palate margin:
- Negative for tumour.
2. Right partial maxillectomy:
- Squamous cell carcinoma, well differentiated.
- 1. The maximum dimension of the tumour is 1.3 cm.
- 2. The maximum thickness of the tumour is 0.5 cm.
- 3. No lymphovascular or perineural invasion identified.
- 1. Bone and bone margins are negative for tumour.
- 2. All other margins are negative for tumour.
3. Right partial glossectomy:
- Squamous cell carcinoma in-situ (CIS), focally suspicious for superficial invasion.
- 1. Maximum lesional dimension 0.6 cm.
- 2. Maximum lesional thickness 0.1 cm.
- 3. All margins are negative for tumour (see comment).
- 1. Deep margin of tongue.
- Negative for tumour.

SYNOPTIC DATA

Specimen Type: Resection: Right partial maxillectomy.

Tumor Site: Oral Cavity

Histologic Type: Squamous cell carcinoma, conventional

Tumor Size: Greatest dimension: 1.3 cm

[page 2 of 4]
Tumor thickness: 0.5 cm

Histologic Grade: G1: Well differentiated

Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent

Perineural Invasion: Absent

Margins: Margins uninvolved by tumor

Pathologic Staging (pTNM): pT1: Tumor of lip or oral cavity 2 cm or less in greatest dimension

pNX: Regional lymph nodes cannot be assessed for aerodigestive sites

PMX: Distant metastasis cannot be assessed

COMMENT

3. The "tumour" arising on the right tongue shows squamous cell carcinoma in-situ (CIS), at least. Focally the lesion shows ulceration and within this area there is a focus suspicious for superficial invasion. It appears to be arising in a "field-effect" of abnormal squamous mucosa that shows keratosis and varies gradually from minimal/mild atypia to moderate dysplasia. While the margins are negative for overt dysplasia, they do not appear entirely normal.

ELECTRONICALLY VERIFIED BY

CLINICAL HISTORY

Oral ca

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and as "medial margin palate". It consists of 3 bony fragments of tissue measuring 0.2 x 0.1 x 0.1 to 0.3 x 0.2 x 0.1 cm. The specimen is submitted in toto.

1A medial margin palate

2. The specimen is labeled with the patient's name and as right partial maxillectomy. It consists of upper right jaw measuring 4.5AP x 1.8 SI x 2ML cm. It includes a portion of maxilla with 2 teeth. There is a tumor arising in the alveolar ridge. The tumor measures 1.3 AP x 0.5 SI x 1.2 ML cm. The tumor is raised and partly hemorrhagic. There is no involvement of bone by the tumour. The tumor is located at 0.2 cm from the closest medial mucosal margin. Remaining margins are as follows: lateral mucosa margin 0.6cm; 1.5cm from posterior mucosal margin; 0.7cm anterior mucosal margin. The lateral margin is painted with green dye and the medial India ink. Representative sections are submitted.

2A medial mucosal margin

2B lateral mucosal margin

2C anterior mucosal margin

[page 3 of 4]
2D posterior mucosal margin

2E-2G tumor

2H anterior maxilla margin, in decal

2I posterior maxilla margin, decal

2J mid section through bone, decal

3. The specimen is labeled the patient's name and as "right partial glossectomy stitch anterior margin". It consists of a portion of right ventral tongue measuring 2.8 SI x 1.1 ML x 3.1 AP cm. There is a suture orientation. There is a superficial ulcerated tumor involving the lateral surface of the tongue. The tumor measures 0.5 SI x 0.1 ML x 0.6 AP cm. It is located at 1.0 cm from the medial margin, 1 cm from the anterior margin, and 1.5 from the posterior margin; 1.1 cm from the inferior mucosal margin. The remaining tongue mucosa shows white plaques at 0.9 cm from the anterior edge of the tumor. These plaques measure 0.6 x 0.2 cm in aggregate. Representative sections are submitted.

3A anterior margin

3B superior margin

3C inferior margin

3D posterior margin

3E medial margin

3F-3G tumor in toto

3H plaque

4. The specimen is labeled with the patient's name and as "deep margin tongue". It consists of a fragment of tissue measuring 0.9 x 0.8 x 0.4 cm. The specimen is submitted in toto for frozen section.

4A deep margin tongue

Source: NCI Genomic Data Commons file 5dd5d8fb-a57b-4a2a-86ab-40185d3d4c2e (TCGA-CQ-7063.BE787B58-3A45-427D-98AF-68996BB3F337.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).